Somatic mutation profile of tumor specimen TCGA-A6-6780-01A (aliquot TCGA-A6-6780-01A-11D-1835-10) from TCGA case TCGA-A6-6780, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 74.6 years (27,250 days).
Specimen TCGA-A6-6780-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23a475d0-59da-485b-b625-4d6a60d072cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-6780-10A (Blood Derived Normal), aliquot TCGA-A6-6780-10A-01D-A270-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d35c479f-a4f4-4d81-90f8-f97ee6700ab9

The open-access MAF lists 1,307 somatic variants for this specimen: 1,019 protein-altering or splice-affecting, 263 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 649, Silent 263, Frame Shift Del 219, Frame Shift Ins 60, Nonsense Mutation 41, Splice Site 26, Splice Region 12, In Frame Del 9, RNA 9, Intron 8, 3'UTR 4, 3'Flank 2.

Variants (750 of 1,307; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALOX12B | c.1350dup p.L451Afs*27 | Frame Shift Ins (INS) | VAF 11/42 reads (26%) | catalogued as rs746723399; ClinVar: pathogenic; called by mutect2, varscan2
- ARHGEF9 | c.1012C>T p.R338W | Missense Mutation (SNP) | VAF 4/7 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs869312941, CM1514576, COSV53635998; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- B4GALNT1 | c.263del p.G88Afs*24 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs745744124; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BLM | c.1544del p.N515Mfs*16 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | catalogued as rs367543043; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CTNNB1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 59/84 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs121913409, COSV62687872, COSV62688307, COSV62689938, COSV62711475; ClinVar: other / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CYP27B1 | c.171dup p.L58Afs*275 | Frame Shift Ins (INS) | VAF 15/57 reads (26%) | catalogued as rs763437121; ClinVar: pathogenic; called by mutect2, varscan2
- FLG | c.477dup p.E160Rfs*10 | Frame Shift Ins (INS) | VAF 61/213 reads (29%) | catalogued as rs746683647; ClinVar: pathogenic; called by mutect2, varscan2
- GAA | c.258dup p.N87Qfs*9 | Frame Shift Ins (INS) | VAF 9/27 reads (33%) | catalogued as rs761317813; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- LDLR | c.1946del p.P649Qfs*16 | Frame Shift Del (DEL) | VAF 11/43 reads (26%) | catalogued as rs879255082; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MAGEC1 | c.3138A>C p.K1046N | Missense Mutation (SNP) | VAF 6/18 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as rs753057119, COSV53569304, COSV53569381; called by mutect2, varscan2
- MLH1 | c.199G>A p.G67R | Missense Mutation (SNP) | VAF 41/60 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs63750206, CM093753, CM970953, CM990854, COSV51614574, COSV51617724; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NEK1 | c.1908del p.V637Cfs*34 | Frame Shift Del (DEL) | VAF 58/156 reads (37%) | catalogued as rs775849720; ClinVar: likely pathogenic; called by mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 26/73 reads (36%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- SMAD2 | c.961C>T p.R321* | Nonsense Mutation (SNP) | VAF 26/67 reads (39%) | hotspot (GDC flag); catalogued as rs776149698, COSV50993232; called by muse, mutect2, varscan2
- WDR19 | c.641dup p.L214Ffs*5 | Frame Shift Ins (INS) | VAF 24/72 reads (33%) | catalogued as rs587777348; ClinVar: pathogenic; called by mutect2, varscan2
- A2M | c.3190A>G p.T1064A | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.133); catalogued as COSV59383171; called by muse, mutect2, varscan2
- ABCA1 | c.6779A>G p.Y2260C | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV66063942; called by muse, mutect2, varscan2
- ABCA10 | c.2518G>A p.V840M | Missense Mutation (SNP) | VAF 76/222 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.298); catalogued as rs188482429, COSV52229314; called by muse, varscan2
- ABCA12 | c.7265C>T p.P2422L (on ENST00000272895 / NM_173076.3; = p.P2104L on NM_015657.3) | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765289715, COSV55949978; called by muse, mutect2, varscan2
- ABCA13 | c.14078T>C p.V4693A | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.067); catalogued as rs1401940414, COSV68943668; called by muse, mutect2, varscan2
- ABCA6 | c.4184+1G>A p.X1395_splice | Splice Site (SNP) | VAF 6/20 reads (30%) | catalogued as COSV99445945; called by mutect2, varscan2
- ABCC4 | c.3655del p.I1219Sfs*11 | Frame Shift Del (DEL) | VAF 28/81 reads (35%) | catalogued as rs756859429, COSV65316407; called by mutect2, varscan2
- ABCD1 | c.1780G>T p.G594C | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM104021, COSV54383503; called by muse, mutect2, varscan2
- ABL2 | c.500G>A p.S167N (on ENST00000502732 / NM_007314.4; = p.S152N on NM_005158.5) | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV61011187; called by muse, mutect2, varscan2
- ABR | c.2526dup p.I843Hfs*46 (on ENST00000302538 / NM_021962.5; = p.I806Hfs*46 on NM_001092.5) | Frame Shift Ins (INS) | VAF 12/34 reads (35%) | catalogued as rs750897785; called by mutect2, varscan2
- ACAD10 | c.2966C>T p.A989V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100563871; called by muse, mutect2, varscan2
- ACKR3 | c.137C>T p.T46M | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as rs200114828, COSV56020600, COSV56021961; called by muse, mutect2, varscan2
- ACKR3 | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.873); catalogued as rs747331262, COSV56020531; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 32/50 reads (64%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM12 | c.2561dup p.Q855Sfs*55 | Frame Shift Ins (INS) | VAF 7/30 reads (23%) | catalogued as rs758654497; called by mutect2, pindel, varscan2
- ADAM28 | c.224del p.N75Tfs*53 | Frame Shift Del (DEL) | VAF 46/145 reads (32%) | catalogued as rs570442888; called by mutect2, varscan2
- ADAMTS19 | c.1296G>A p.M432I | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50732765, COSV50768497; called by muse, varscan2
- ADAMTS19 | c.1321A>G p.I441V | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.087); catalogued as COSV50732788, COSV50796372; called by muse, varscan2
- ADAMTS4 | c.2206T>C p.Y736H | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63489361; called by muse, mutect2, varscan2
- ADGRL3 | c.3781G>A p.G1261R (on ENST00000506720 / NM_001322402.2; = p.G1193R on NM_015236.6) | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72229458; called by muse, mutect2, varscan2
- ADIPOR2 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as rs750803822, COSV63945473; called by muse, mutect2, varscan2
- ADO | c.532G>T p.E178* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as COSV65677673; called by muse, mutect2, varscan2
- AGA | c.710A>G p.D237G | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1295588617, COSV52805762; called by muse, mutect2, varscan2
- AHNAK2 | c.7549G>A p.G2517R | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs757038774, COSV60908458; called by mutect2, varscan2
- AK9 | c.3633+7A>G | Splice Region (SNP) | VAF 7/14 reads (50%) | catalogued as rs1188378171, COSV100393236; called by muse, mutect2, varscan2
- AKAP12 | c.1904T>C p.L635P | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV99482636; called by muse, mutect2
- AKT2 | c.401A>G p.E134G | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100251443; called by muse, mutect2, varscan2
- ALDH3A1 | c.1334del p.P445Rfs*6 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | catalogued as rs778623472, COSV56735668; called by mutect2, pindel
- ALPK2 | c.1067del p.L356Yfs*2 | Frame Shift Del (DEL) | VAF 21/61 reads (34%) | catalogued as rs756508755; called by mutect2, pindel, varscan2
- ANGPTL1 | c.403A>G p.M135V | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.81); catalogued as COSV52365423; called by muse, mutect2, varscan2
- ANK1 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV55873507; called by muse, mutect2, varscan2
- ANK3 | c.447G>T p.Q149H | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99778609; called by muse, mutect2, varscan2
- ANO3 | c.2735C>T p.A912V | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56781405; called by muse, mutect2, varscan2
- ANO7 | c.1733G>A p.R578H (on ENST00000274979; = p.R524H on NM_001370694.2) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs778300142, COSV51468501, COSV51469706; called by mutect2, varscan2
- ANOS1 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.937); catalogued as rs1404298787, COSV52916162; called by muse, mutect2, varscan2
- ANXA10 | c.17A>G p.Y6C | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV63738070; called by muse, mutect2, varscan2
- ANXA13 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 58/167 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV51621308; called by muse, mutect2, varscan2
- AP1G2 | c.1345dup p.A449Gfs*49 | Frame Shift Ins (INS) | VAF 15/51 reads (29%) | catalogued as rs749982998; called by mutect2, varscan2
- AP4B1 | c.1939C>T p.P647S | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.74); catalogued as COSV56723451; called by muse, mutect2, varscan2
- APBB2 | c.327G>C p.K109N | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55947499; called by muse, mutect2
- APOBR | c.1365C>A p.D455E (on ENST00000431282; = p.D464E on NM_018690.4) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.07); catalogued as COSV60488801; called by muse, mutect2, varscan2
- APOLD1 | c.509A>G p.E170G (on ENST00000326765 / NM_001130415.2; = p.E139G on NM_030817.3) | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV58731926; called by muse, mutect2, varscan2
- ARFGEF2 | c.1205G>A p.R402H | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs762557818, COSV64210624; called by muse, mutect2, varscan2
- ARHGAP11A | c.1306C>T p.R436C | Missense Mutation (SNP) | VAF 82/156 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760030538, COSV64380588; called by muse, mutect2, varscan2
- ARHGAP21 | c.3422C>T p.A1141V | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as COSV57602364; called by muse, mutect2, varscan2
- ARHGAP39 | c.1802G>A p.R601Q | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV52767260; called by muse, mutect2, varscan2
- ARHGAP45 | c.1618T>C p.Y540H | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV57429435; called by muse, mutect2, varscan2
- ARHGEF17 | c.1589C>T p.T530M | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.151); catalogued as rs573060878, COSV55229676; called by muse, mutect2, varscan2
- ARHGEF19 | c.1772G>A p.R591H | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs781061684, COSV54615135; called by muse, mutect2, varscan2
- ARHGEF19 | c.1357G>A p.D453N | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV54615145; called by muse, mutect2, varscan2
- ARHGEF26 | c.1159G>A p.A387T | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as COSV62843991; called by muse, mutect2, varscan2
- ARID1B | c.3176G>A p.W1059* | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | catalogued as rs1554231204, COSV99266845, COSV99267605; called by muse, mutect2
- ARRB2 | c.114A>G p.V38= | Splice Region (SNP) | VAF 17/48 reads (35%) | catalogued as rs1288113694, COSV52616534; called by muse, mutect2, varscan2
- ARSJ | c.1736dup p.K580Efs*32 | Frame Shift Ins (INS) | VAF 17/56 reads (30%) | catalogued as rs753865255; called by mutect2, varscan2
- ART5 | c.347C>T p.T116M | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.097); catalogued as rs138160202, COSV63364075; called by muse, mutect2, varscan2
- ASAH1 | c.341A>G p.D114G | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV100025569; called by muse, mutect2, varscan2
- ASB15 | c.1745G>A p.G582E | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as COSV51923861; called by muse, mutect2, varscan2
- ASNSD1 | c.414dup p.G139Wfs*4 | Frame Shift Ins (INS) | VAF 64/215 reads (30%) | catalogued as rs759722534; called by mutect2, varscan2
- ATG2B | c.5261G>T p.R1754M | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.34); catalogued as COSV55889435; called by muse, mutect2, varscan2
- ATM | c.5918G>T p.R1973I | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV53727536, COSV53745448; called by muse, mutect2, varscan2
- ATP13A2 | c.3257C>T p.A1086V | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs370677966; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP13A2 | c.556A>G p.S186G | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV58698280; called by muse, mutect2, varscan2
- ATP13A5 | c.131G>A p.C44Y | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.616); catalogued as rs1183113946, COSV60866043; called by muse, mutect2, varscan2
- ATP2A2 | c.2465A>G p.N822S | Missense Mutation (SNP) | VAF 45/201 reads (22%) | SIFT tolerated (0.98); PolyPhen benign (0.01); catalogued as COSV57875055; called by muse, mutect2, varscan2
- ATP6V0D1 | c.386G>A p.C129Y | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52096827; called by muse, mutect2, varscan2
- AVPR1A | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1481652349, COSV54545684; called by muse, mutect2, varscan2
- AXDND1 | c.1312A>G p.I438V | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV62639900; called by muse, mutect2
- B3GNT7 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751482955, COSV55005845; called by muse, mutect2, varscan2
- BCL9L | c.1346del p.P449Lfs*14 | Frame Shift Del (DEL) | VAF 10/20 reads (50%) | catalogued as rs754310793, COSV52681762; called by mutect2, pindel, varscan2
- BEST2 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.147); catalogued as COSV50359057; called by muse, mutect2, varscan2
- BICDL1 | c.1096C>G p.L366V | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as COSV57493518, COSV99985761; called by muse, mutect2, varscan2
- BICRA | c.2810del p.P937Hfs*10 | Frame Shift Del (DEL) | VAF 18/62 reads (29%) | catalogued as rs755506199; called by mutect2, varscan2
- BIN3 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs372409275; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2226T>G p.H742Q | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV63243945; called by muse, mutect2, varscan2
- BNC1 | c.1657A>C p.I553L | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as COSV61756569; called by muse, mutect2, varscan2
- BPTF | c.1376A>G p.E459G | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV58831793; called by muse, mutect2, varscan2
- BRD3 | c.1102C>T p.R368* | Nonsense Mutation (SNP) | VAF 20/48 reads (42%) | catalogued as rs1236927541, COSV57701549; called by muse, mutect2, varscan2
- BRD4 | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV54582580; called by muse, mutect2, varscan2
- BSN | c.4222C>T p.R1408C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs143474442, COSV99609730; called by muse, mutect2, varscan2
- BTBD2 | c.824T>C p.L275P | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1448331455, COSV99724573; called by muse, mutect2, varscan2
- BTBD7 | c.3194C>T p.T1065I | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.991); catalogued as COSV58283690; called by muse, mutect2, varscan2
- BTRC | c.1780del p.R594Vfs*14 (on ENST00000370187 / NM_033637.4; = p.R558Vfs*14 on NM_003939.5) | Frame Shift Del (DEL) | VAF 26/93 reads (28%) | catalogued as rs774921343; called by mutect2, pindel, varscan2
- BUB1 | c.1063C>A p.P355T | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.15); catalogued as COSV57061345; called by muse, mutect2, varscan2
- BVES | c.960T>C p.H320= | Splice Region (SNP) | VAF 25/76 reads (33%) | catalogued as COSV100114708; called by muse, mutect2, varscan2
- C15orf39 | c.1127_1128del p.L376Qfs*8 | Frame Shift Del (DEL) | VAF 9/40 reads (23%) | catalogued as rs759475579, COSV62295808; called by mutect2, pindel, varscan2
- C16orf70 | c.947A>G p.H316R | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54625685; called by muse, mutect2, varscan2
- C19orf53 | c.98-2A>G p.X33_splice | Splice Site (SNP) | VAF 39/104 reads (38%) | catalogued as COSV50003690, COSV50004559; called by muse, mutect2, varscan2
- C1S | c.1972del p.Q658Sfs*11 | Frame Shift Del (DEL) | VAF 9/38 reads (24%) | catalogued as COSV61071225; called by mutect2, pindel, varscan2
- C1orf74 | c.233T>C p.F78S | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV99160326; called by muse, mutect2, varscan2
- C9orf40 | c.470G>T p.R157M | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65228363; called by muse, mutect2, varscan2
- CABYR | c.1037C>T p.S346F | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.053); catalogued as rs1378103036, COSV59110225; called by muse, mutect2, varscan2
- CACNA1D | c.736C>T p.R246* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as COSV55438145; called by muse, mutect2, varscan2
- CACNA1E | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs1299132420, COSV62383135, COSV62387665; called by muse, mutect2, varscan2
- CACNA1E | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1172205004, COSV62386234; called by muse, mutect2, varscan2
- CACNA1G | c.1640del p.P547Lfs*17 | Frame Shift Del (DEL) | VAF 16/30 reads (53%) | catalogued as rs767555827; called by mutect2, varscan2
- CACNA1G | c.2307G>T p.E769D | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV61720483; called by muse, mutect2, varscan2
- CACNG5 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs758742270, COSV50054770; called by muse, mutect2, varscan2
- CALY | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.995); catalogued as COSV53310061; called by muse, mutect2, varscan2
- CAMK2B | c.1843G>A p.A615T | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs757820225, COSV51657597; called by muse, mutect2, varscan2
- CAPN7 | c.1453T>C p.W485R | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53776852; called by muse, mutect2
- CASR | c.2013del p.S672Qfs*28 (on ENST00000490131; = p.S749Qfs*28 on NM_000388.4) | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | catalogued as COSV56134396; called by mutect2, pindel, varscan2
- CASR | c.2573C>T p.P858L (on ENST00000490131; = p.P935L on NM_000388.4) | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs201950717, COSV56134409; called by muse, mutect2, varscan2
- CASTOR1 | c.127A>C p.S43R | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99304507; called by muse, mutect2, varscan2
- CATSPER4 | c.1024C>T p.P342S | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.162); catalogued as rs751979500, COSV58792342; called by muse, mutect2, varscan2
- CAVIN1 | c.506G>A p.S169N | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.14); PolyPhen benign (0.092); catalogued as COSV63811428; called by muse, mutect2, varscan2
- CBFA2T3 | c.1405G>A p.V469M | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs1473927688, COSV51923456; called by muse, mutect2, varscan2
- CC2D1B | c.524A>G p.H175R | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV99429708; called by muse, mutect2
- CCDC148 | c.1249A>T p.K417* | Nonsense Mutation (SNP) | VAF 9/17 reads (53%) | catalogued as COSV99319831; called by muse, mutect2, varscan2
- CCDC27 | c.1714C>T p.R572C | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs746602099, COSV53898512; called by muse, mutect2, varscan2
- CCDC27 | c.1915del p.L639Cfs*8 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs751021664; called by mutect2, pindel, varscan2
- CCDC39 | c.1084G>C p.E362Q | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV56479007; called by muse, mutect2, varscan2
- CCKBR | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs145658504; called by muse, mutect2, varscan2
- CD151 | c.641C>T p.T214I | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV58989187; called by muse, mutect2, varscan2
- CD28 | c.589del p.R197Afs*83 | Frame Shift Del (DEL) | VAF 19/70 reads (27%) | catalogued as COSV100142596; called by mutect2, pindel, varscan2
- CD8B | c.728C>T p.T243I (on ENST00000331469 / NM_172213.4; = p.T213I on NM_172102.4) | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV58925095; called by muse, mutect2, varscan2
- CDADC1 | c.581C>A p.P194H | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV51910340; called by muse, mutect2, varscan2
- CDC16 | c.1739T>G p.L580R | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.085); catalogued as COSV52957887; called by muse, mutect2, varscan2
- CDC40 | c.35A>G p.Y12C | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs1440465695, COSV99661087; called by muse, mutect2, varscan2
- CDC45 | c.1516G>A p.V506M | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.052); catalogued as rs12158840, COSV54243551; called by muse, mutect2, varscan2
- CDH11 | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.558); catalogued as COSV51751894; called by muse, mutect2, varscan2
- CDH18 | c.100A>G p.M34V | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV99935054; called by muse, mutect2
- CDH5 | c.1886G>C p.R629P | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.709); catalogued as COSV100439041; called by mutect2, varscan2
- CDIP1 | c.20del p.P7Lfs*29 | Frame Shift Del (DEL) | VAF 36/93 reads (39%) | catalogued as COSV99566654; called by mutect2, pindel, varscan2
- CDK12 | c.3898G>A p.A1300T (on ENST00000447079 / NM_016507.4; = p.A1291T on NM_015083.3) | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.489); catalogued as rs769197936, COSV70999354; called by muse, mutect2, varscan2
- CDR2 | c.772C>T p.R258* | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | catalogued as rs770035745, COSV51675255; called by muse, mutect2, varscan2
- CEMIP | c.540dup p.E181* | Frame Shift Ins (INS) | VAF 19/70 reads (27%) | catalogued as rs753314096; called by mutect2, varscan2
- CEP192 | c.4889C>T p.T1630M | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs749692097, COSV58060205; called by muse, varscan2
- CEP192 | c.7230A>G p.I2410M | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as COSV58060216; called by muse, mutect2, varscan2
- CFAP206 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs757635858, COSV51532616; called by muse, varscan2
- CFH | c.1312C>A p.P438T | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV62776366; called by muse, mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | catalogued as rs751548647; called by mutect2, varscan2
- CHRNB3 | c.646G>A p.G216S | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.297); catalogued as rs1383226244, COSV51493323; called by muse, mutect2, varscan2
- CHST11 | c.427A>G p.K143E | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.534); catalogued as COSV100359085; called by muse, mutect2, varscan2
- CHST15 | c.139G>A p.V47M | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.615); catalogued as rs1374287131, COSV60560314; called by muse, mutect2, varscan2
- CLIP2 | c.2225A>G p.Y742C | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV56274881; called by muse, mutect2, varscan2
- CLPTM1 | c.1177G>A p.V393M | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV61611069; called by muse, mutect2, varscan2
- CLSPN | c.389C>A p.P130H | Missense Mutation (SNP) | VAF 55/159 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV52047095, COSV52051723; called by muse, mutect2, varscan2
- CMYA5 | c.5735G>T p.G1912V | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.231); catalogued as rs1339697814, COSV101483860, COSV71404139; called by muse, mutect2, varscan2
- CNGA4 | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as rs772435211, COSV66005122; called by muse, mutect2, varscan2
- CNNM2 | c.274del p.A92Rfs*4 | Frame Shift Del (DEL) | VAF 20/53 reads (38%) | catalogued as rs768722573; called by mutect2, pindel, varscan2
- CNNM4 | c.1312dup p.L438Pfs*9 | Frame Shift Ins (INS) | VAF 20/69 reads (29%) | catalogued as rs746879923; called by mutect2, pindel, varscan2
- CNR1 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs1274654924, COSV62986467; called by muse, mutect2, varscan2
- CNTFR | c.746T>A p.L249H | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV63633186; called by muse, mutect2, varscan2
- CNTN5 | c.1141C>A p.R381S | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as COSV54283284, COSV54294122; called by muse, mutect2, varscan2
- COG4 | c.799A>G p.R267G | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60421327; called by muse, mutect2, varscan2
- COL11A2 | c.3392G>A p.R1131Q (on ENST00000341947 / NM_080680.3; = p.R1024Q on NM_080679.2) | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs529015303, CM1310538, COSV59493762; called by muse, mutect2, varscan2
- COL20A1 | c.88G>A p.G30S | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.072); catalogued as rs765067131, COSV58912072; called by muse, mutect2, varscan2
- COL6A2 | c.376A>G p.S126G | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV55999370; called by muse, mutect2, varscan2
- COL6A2 | c.2917G>A p.V973M | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs145959270; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- COL6A6 | c.2275G>A p.G759S | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.401); catalogued as COSV62018349; called by muse, mutect2, varscan2
- COL6A6 | c.5588C>T p.T1863M | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.066); catalogued as rs941052860, COSV62016883; called by muse, mutect2, varscan2
- COL7A1 | c.2552G>A p.R851H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.832); catalogued as rs202126339, COSV60391510; called by muse, mutect2, varscan2
- COLGALT2 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1259438301, COSV100730440; called by muse, mutect2, varscan2
- COMP | c.415del p.R139Efs*107 | Frame Shift Del (DEL) | VAF 13/44 reads (30%) | catalogued as COSV55876011; called by mutect2, pindel, varscan2
- COPS7A | c.668C>T p.T223M | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as rs1332744385, COSV57526230; called by muse, mutect2, varscan2
- CPED1 | c.1127T>C p.V376A | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV59997496; called by muse, mutect2, varscan2
- CPLX1 | c.344G>A p.S115N | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV58375305; called by muse, mutect2, varscan2
- CPN1 | c.163G>A p.V55M | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.935); catalogued as rs1272140911, COSV64941958; called by muse, mutect2, varscan2
- CPZ | c.851G>A p.R284H (on ENST00000360986 / NM_001014447.3; = p.R273H on NM_003652.3) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753166608, COSV59921874; called by muse, mutect2, varscan2
- CRTC1 | c.8C>T p.T3I | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as COSV58716575; called by muse, mutect2, varscan2
- CSMD3 | c.10895C>T p.A3632V (on ENST00000297405 / NM_001363185.1; = p.A3463V on NM_052900.3) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52107676; called by muse, mutect2, varscan2
- CTNNA1 | c.2397G>T p.E799D | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.88); PolyPhen benign (0.071); catalogued as COSV57069808; called by muse, mutect2, varscan2
- CTNNA2 | c.249A>C p.Q83H | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as COSV63547847, COSV63575801; called by muse, mutect2
- CTNNBL1 | c.1024A>G p.M342V | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV100799353; called by muse, mutect2, varscan2
- CTTNBP2 | c.2307A>C p.Q769H | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.863); catalogued as COSV99353235; called by muse, mutect2
- CYP26B1 | c.1090C>A p.L364M | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.656); catalogued as COSV50010796; called by muse, mutect2, varscan2
- CYP2A7 | c.831G>T p.E277D | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV52497580; called by muse, mutect2, varscan2
- CYP4B1 | c.607G>T p.G203C | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV54721345; called by muse, mutect2, varscan2
- CYP4F8 | c.1073T>C p.V358A | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as rs1395666880, COSV100358030; called by muse, mutect2, varscan2
- CYP4Z1 | c.886A>T p.T296S | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV61963854; called by muse, mutect2, varscan2
- DACT1 | c.1682C>T p.P561L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV100241777, COSV60019474; called by muse, mutect2, varscan2
- DAXX | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1380709730, COSV99801587; called by muse, mutect2
- DCAF15 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.229); catalogued as rs1236691828, COSV99586716; called by muse, varscan2
- DDB1 | c.568G>A p.V190I | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.105); catalogued as rs781465869, COSV57101136, COSV57101337; called by muse, mutect2, varscan2
- DDX27 | c.407A>C p.K136T | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV65629033; called by muse, mutect2, varscan2
- DEDD | c.897_899del p.E299del | In Frame Del (DEL) | VAF 34/87 reads (39%) | catalogued as rs1262577401; called by pindel, varscan2
- DEDD | c.56A>G p.Q19R | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100919037; called by muse, mutect2, varscan2
- DEFB106B | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 57/527 reads (11%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.021); catalogued as rs1340865148, COSV100128875; called by muse, varscan2
- DGCR2 | c.1499C>T p.A500V | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs746952262, COSV54216550; called by muse, mutect2, varscan2
- DGKD | c.3565G>A p.V1189M (on ENST00000264057 / NM_152879.3; = p.V1145M on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs907402698, COSV51033585; called by muse, mutect2, varscan2
- DIP2B | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.329); catalogued as rs1411593406, COSV56579162; called by muse, mutect2, varscan2
- DIXDC1 | c.1972A>T p.I658F (on ENST00000440460 / NM_001037954.4; = p.I447F on NM_033425.4) | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as COSV100180108; called by muse, mutect2, varscan2
- DLC1 | c.3289C>T p.Q1097* (on ENST00000276297 / NM_001348081.2; = p.Q660* on NM_006094.5) | Nonsense Mutation (SNP) | VAF 19/44 reads (43%) | catalogued as COSV52291104, COSV52333026; called by muse, mutect2, varscan2
- DLG4 | c.2072T>C p.I691T (on ENST00000399506 / NM_001321075.3; = p.I734T on NM_001365.4) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as COSV57236736; called by muse, mutect2, varscan2
- DNAH17 | c.7020del p.D2341Tfs*111 | Frame Shift Del (DEL) | VAF 13/27 reads (48%) | catalogued as rs769976401; called by mutect2, pindel, varscan2
- DNAH3 | c.6829G>A p.D2277N | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780707324, COSV54504614; called by muse, mutect2, varscan2
- DNAH5 | c.9347G>A p.R3116Q | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.187); catalogued as rs745557874, COSV54205144; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.5927del p.G1976Efs*78 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs1233412023, COSV54222791; called by mutect2, varscan2
- DNAH9 | c.11481T>G p.F3827L | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.06); catalogued as rs558596178, COSV52335277; called by muse, mutect2, varscan2
- DNAJA4 | c.620_622del p.K207del (on ENST00000343789; = p.K236del on NM_018602.3) | In Frame Del (DEL) | VAF 8/30 reads (27%) | catalogued as rs1279146209; called by pindel, varscan2
- DNAJB7 | c.884del p.K295Rfs*25 | Frame Shift Del (DEL) | VAF 98/298 reads (33%) | catalogued as rs768619916; called by mutect2, varscan2
- DNAJC1 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 50/190 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63283698; called by muse, mutect2, varscan2
- DNAJC8 | c.417dup p.Q140Tfs*15 | Frame Shift Ins (INS) | VAF 44/134 reads (33%) | catalogued as rs1557706537; called by mutect2, varscan2
- DOCK3 | c.5145G>T p.Q1715H | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.541); catalogued as COSV56504348; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 13/59 reads (22%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK6 | c.2671G>T p.A891S | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV53911314; called by muse, mutect2, varscan2
- DPM2 | c.21G>T p.Q7H | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55947409; called by muse, mutect2, varscan2
- DRAP1 | c.518dup p.T174Dfs*23 | Frame Shift Ins (INS) | VAF 22/80 reads (28%) | catalogued as rs751570365; called by pindel, varscan2
- DSC2 | c.473A>G p.Q158R | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.612); catalogued as COSV99199523; called by muse, mutect2, varscan2
- DSCAM | c.806G>A p.G269E | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0.037); catalogued as COSV68021303; called by muse, mutect2, varscan2
- DSG4 | c.2510A>G p.D837G | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs559395133, COSV57388422; called by muse, mutect2, varscan2
- DSPP | c.1646G>A p.S549N | Missense Mutation (SNP) | VAF 61/166 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.028); catalogued as COSV56808064; called by muse, mutect2, varscan2
- DST | c.13435G>T p.G4479C (on ENST00000361203 / NM_001374722.1; = p.G2067C on NM_015548.5) | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs764892491, COSV54998841; called by muse, mutect2, varscan2
- DYNC1H1 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.66); catalogued as rs201746558, COSV64134550; called by muse, varscan2
- E2F8 | c.2505C>A p.S835R | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as COSV51462000; called by muse, mutect2, varscan2
- E2F8 | c.937A>T p.R313W | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51462014; called by muse, mutect2, varscan2
- E2F8 | c.502C>T p.H168Y | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51462024; called by muse, mutect2, varscan2
- EBF1 | c.1055T>A p.I352N | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV58168299; called by muse, mutect2, varscan2
- EBPL | c.516del p.F172Lfs*7 | Frame Shift Del (DEL) | VAF 36/79 reads (46%) | catalogued as rs369293935; called by mutect2, varscan2
- ECHS1 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (1); PolyPhen possibly damaging (0.757); catalogued as rs575638199, COSV53369254, COSV99529500; called by muse, mutect2, varscan2
- EEF2K | c.1036G>T p.A346S | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.135); catalogued as COSV53778883; called by muse, mutect2, varscan2
- EFCAB5 | c.450del p.K150Nfs*17 | Frame Shift Del (DEL) | VAF 26/54 reads (48%) | catalogued as rs760813779; called by mutect2, varscan2
- EFCAB6 | c.2155del p.S719Vfs*3 | Frame Shift Del (DEL) | VAF 35/132 reads (27%) | catalogued as COSV99412746; called by mutect2, pindel, varscan2
- EFNA5 | c.644T>C p.L215S | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.766); catalogued as COSV60944928; called by muse, mutect2
- EGR1 | c.992C>T p.T331M | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1230522969, COSV53518023; called by muse, mutect2, varscan2
- EGR1 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53518033; called by muse, mutect2, varscan2
- EIF3B | c.1402A>C p.K468Q | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.08); catalogued as COSV62802724; called by muse, varscan2
- EIF4B | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.097); catalogued as rs753615463, COSV50401645; called by muse, mutect2, varscan2
- EIF4G1 | c.3429-2A>G p.X1143_splice (on ENST00000346169 / NM_198241.3; = p.X948_splice on NM_004953.5) | Splice Site (SNP) | VAF 10/28 reads (36%) | catalogued as COSV100071538; called by muse, mutect2
- ELOA | c.1850G>A p.R617H | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as rs1213533133, COSV69309466; called by muse, mutect2, varscan2
- ELP1 | c.1630C>T p.Q544* | Nonsense Mutation (SNP) | VAF 16/41 reads (39%) | catalogued as COSV65896337; called by muse, mutect2, varscan2
- ENOX1 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1241501313, COSV54888070; called by muse, mutect2, varscan2
- ENPP7 | c.850G>T p.G284W | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as COSV60385452; called by muse, mutect2, varscan2
- EP300 | c.5485C>T p.R1829C | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV54326029; called by muse, mutect2, varscan2
- EPB41L3 | c.2293C>T p.R765* | Nonsense Mutation (SNP) | VAF 50/128 reads (39%) | catalogued as COSV59448921; called by muse, mutect2, varscan2
- EPHA6 | c.256G>T p.E86* | Nonsense Mutation (SNP) | VAF 33/89 reads (37%) | catalogued as COSV67560082, COSV67590874; called by muse, mutect2, varscan2
- EPRS1 | c.1433A>G p.Q478R | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV65097204; called by muse, mutect2, varscan2
- ERMP1 | c.1951del p.T651Pfs*3 | Frame Shift Del (DEL) | VAF 34/122 reads (28%) | catalogued as rs753821453; called by mutect2, varscan2
- ESYT1 | c.2922G>T p.Q974H | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV57271754; called by muse, mutect2, varscan2
- ESYT3 | c.2481del p.F827Lfs*7 | Frame Shift Del (DEL) | VAF 18/63 reads (29%) | catalogued as rs772672190; called by mutect2, varscan2
- ETV3 | c.174G>T p.Q58H | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV58747741; called by muse, mutect2, varscan2
- EVC2 | c.3850T>G p.S1284A | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.91); catalogued as COSV60388177; called by muse, mutect2
- EXD3 | c.1657G>T p.A553S | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV59803766; called by muse, mutect2, varscan2
- EXOC4 | c.1328+4_1328+7del p.X443_splice | Splice Site (DEL) | VAF 9/32 reads (28%) | catalogued as rs1563079826; called by pindel, varscan2
- F2R | c.1210A>G p.M404V | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV59928476; called by mutect2, varscan2
- FAHD2B | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 23/61 reads (38%) | catalogued as rs751966944; called by mutect2, pindel, varscan2
- FAM117A | c.865C>T p.H289Y | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.201); catalogued as COSV99544519; called by muse, mutect2, varscan2
- FAM151A | c.351del p.T118Lfs*43 | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | catalogued as rs749953492; called by mutect2, pindel, varscan2
- FAM160B1 | c.2263G>A p.A755T | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs138422469, COSV65087282; called by muse, mutect2, varscan2
- FAM167B | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs747746477, COSV61107373; called by muse, mutect2, varscan2
- FAM171A1 | c.2026G>A p.A676T | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.346); catalogued as rs762494380, COSV65313536, COSV65320245; called by muse, mutect2, varscan2
- FAM214A | c.2042del p.N681Mfs*5 | Frame Shift Del (DEL) | VAF 24/51 reads (47%) | catalogued as rs762546731, COSV55927849; called by mutect2, varscan2
- FAM43B | c.283G>A p.V95M | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60579477; called by muse, mutect2, varscan2
- FAM83F | c.1085C>T p.A362V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV100328854; called by muse, mutect2, varscan2
- FAM83H | c.248T>G p.L83R | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.378); catalogued as COSV101186927; called by mutect2, varscan2
- FAM9A | c.477del p.K159Nfs*3 | Frame Shift Del (DEL) | VAF 53/81 reads (65%) | catalogued as rs748967872; called by mutect2, varscan2
- FANCD2 | c.1607T>G p.L536R | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99810522; called by muse, mutect2, varscan2
- FANCM | c.1940A>G p.Y647C | Missense Mutation (SNP) | VAF 53/105 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs1219702984, COSV57497479; called by muse, mutect2, varscan2
- FAS | c.403del p.C135Vfs*52 | Frame Shift Del (DEL) | VAF 24/98 reads (24%) | catalogued as rs1564692984, CX113055, COSV58238368; called by mutect2, pindel, varscan2
- FASTKD5 | c.796dup p.S266Ffs*2 | Frame Shift Ins (INS) | VAF 12/39 reads (31%) | catalogued as rs1436077092; called by mutect2, pindel, varscan2
- FAT2 | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.642); catalogued as rs377151192; called by muse, mutect2, varscan2
- FBH1 | c.2863G>A p.V955I (on ENST00000362091 / NM_178150.3; = p.V1006I on NM_032807.4) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs141977640, COSV62981650; called by muse, mutect2, varscan2
- FBN3 | c.4730del p.G1577Vfs*72 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as COSV54462674; called by mutect2, pindel, varscan2
- FBXL4 | c.1585G>A p.A529T | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV57745040; called by muse, mutect2, varscan2
- FBXO25 | c.833C>A p.A278D (on ENST00000382824 / NM_183421.2; = p.A211D on NM_012173.3) | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); catalogued as COSV52335852; called by muse, mutect2, varscan2
- FBXO5 | c.659T>G p.L220R | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs766507735, COSV57670406; called by muse, mutect2, varscan2
- FBXW5 | c.80T>C p.L27P | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1212103104, COSV99812351; called by muse, mutect2, varscan2
- FCRL3 | c.2111C>T p.A704V | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as COSV63839549; called by muse, mutect2, varscan2
- FKBP15 | c.3595C>T p.R1199C | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.013); catalogued as rs372719818; called by muse, mutect2, varscan2
- FKBP9 | c.384del p.N129Ifs*10 | Frame Shift Del (DEL) | VAF 26/80 reads (33%) | catalogued as rs752076602; called by mutect2, pindel, varscan2
- FLNB | c.1915G>A p.A639T | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs763927755, COSV55871104; called by muse, mutect2, varscan2
- FLT1 | c.1703C>T p.T568M | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.714); catalogued as rs745653714, COSV56718562; called by muse, mutect2, varscan2
- FLT4 | c.1421+1G>A p.X474_splice | Splice Site (SNP) | VAF 11/30 reads (37%) | catalogued as COSV56098976; called by muse, mutect2, varscan2
- FLYWCH1 | c.1688G>A p.R563H (on ENST00000253928 / NM_001308068.2; = p.R562H on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs780119016, COSV54146729, COSV99558613; called by muse, mutect2, varscan2
- FNDC3B | c.3165dup p.T1056Hfs*16 | Frame Shift Ins (INS) | VAF 20/54 reads (37%) | catalogued as rs769012096; called by mutect2, varscan2
- FOXE1 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64300110; called by muse, mutect2, varscan2
- FOXRED2 | c.652A>G p.I218V | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV53398931; called by muse, mutect2, varscan2
- FRAS1 | c.9603del p.C3202Afs*11 | Frame Shift Del (DEL) | VAF 20/65 reads (31%) | catalogued as COSV104394125; called by mutect2, pindel, varscan2
- FREM1 | c.1595T>C p.L532P | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV101083926; called by muse, mutect2
- FRMD4A | c.1259C>T p.T420M | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV52715353; called by muse, mutect2, varscan2
- FRMPD4 | c.3559G>A p.V1187M | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.061); catalogued as COSV66211527; called by muse, mutect2, varscan2
- FRMPD4 | c.3655G>A p.D1219N | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV66211533; called by muse, mutect2, varscan2
- FRYL | c.3985C>T p.R1329* | Nonsense Mutation (SNP) | VAF 42/124 reads (34%) | catalogued as rs778783611, COSV51940262, COSV51946493; called by muse, mutect2, varscan2
- FSTL1 | c.716C>T p.T239M | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.891); catalogued as rs143843913; called by muse, mutect2, varscan2
- FUBP1 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.403); catalogued as COSV53926700; called by muse, mutect2
- GABARAPL1 | c.221A>G p.D74G | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV56770430; called by muse, mutect2, varscan2
- GALR1 | c.283G>A p.V95M | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV55315950; called by muse, mutect2, varscan2
- GANC | c.1742-1G>T p.X581_splice | Splice Site (SNP) | VAF 29/39 reads (74%) | catalogued as COSV58807385; called by muse, mutect2, varscan2
- GARNL3 | c.1309C>T p.R437W | Missense Mutation (SNP) | VAF 63/161 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs763979585, COSV59223900; called by muse, mutect2, varscan2
- GAS6 | c.1796T>A p.V599E | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.526); catalogued as COSV59847411; called by muse, mutect2, varscan2
- GBA2 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62305336; called by muse, mutect2, varscan2
- GBP1 | c.127A>G p.I43V | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.344); catalogued as rs746630945, COSV65082644; called by muse, mutect2, varscan2
- GIMAP8 | c.923C>G p.S308C | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV56229833; called by muse, mutect2, varscan2
- GINS1 | c.515del p.N172Ifs*14 | Frame Shift Del (DEL) | VAF 28/68 reads (41%) | catalogued as rs750227570; called by mutect2, varscan2
- GINS4 | c.546A>G p.I182M | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV52530849; called by muse, mutect2, varscan2
- GJA4 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.398); catalogued as COSV100654646; called by muse, mutect2, varscan2
- GJA5 | c.673G>T p.E225* | Nonsense Mutation (SNP) | VAF 19/43 reads (44%) | catalogued as COSV99605377; called by muse, mutect2, varscan2
- GLUD1 | c.1447G>T p.G483* | Nonsense Mutation (SNP) | VAF 22/74 reads (30%) | catalogued as COSV53277509; called by muse, varscan2
- GNB4 | c.887T>C p.V296A | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.809); catalogued as COSV51708361; called by muse, mutect2, varscan2
- GNB4 | c.409C>T p.R137* | Nonsense Mutation (SNP) | VAF 31/87 reads (36%) | catalogued as rs767993499, COSV51708374; called by muse, mutect2, varscan2
- GOLGB1 | c.823G>C p.V275L | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV61462017; called by muse, mutect2, varscan2
- GORASP2 | c.65T>C p.V22A | Missense Mutation (SNP) | VAF 56/181 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52200865; called by muse, mutect2, varscan2
- GOSR2 | c.100G>A p.E34K (on ENST00000393456 / NM_001321134.1; = p.E52K on NM_004287.5) | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as rs1286041018, COSV56661183; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 52/135 reads (39%) | catalogued as rs370114090; called by mutect2, varscan2
- GP5 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); catalogued as COSV55461726; called by muse, mutect2, varscan2
- GPBP1L1 | c.1165C>G p.H389D | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV51967062, COSV99322025; called by muse, mutect2, varscan2
- GPC3 | c.598G>T p.G200* | Nonsense Mutation (SNP) | VAF 16/33 reads (48%) | catalogued as CM057329, COSV63659293; called by muse, mutect2, varscan2
- GPIHBP1 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as rs776871524, COSV58209018; called by muse, mutect2, varscan2
- GPR19 | c.173A>G p.Y58C | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.387); catalogued as COSV60122929, COSV60124659; called by muse, mutect2, varscan2
- GREB1 | c.5243G>A p.R1748Q | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs769255342, COSV52181196; called by muse, mutect2, varscan2
- GRIK3 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs755366301, COSV66135882, COSV66139002; called by muse, mutect2, varscan2
- GRIN3B | c.2221G>A p.A741T | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV52258749; called by muse, mutect2, varscan2
- GRM2 | c.209A>G p.D70G | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99622509; called by mutect2, varscan2
- GSTM1 | c.457A>G p.I153V | Missense Mutation (SNP) | VAF 40/618 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.957); catalogued as COSV100564397; called by muse, mutect2
- GTF2IRD2 | c.355T>C p.Y119H | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1422871321; called by muse, mutect2, varscan2
- GUCY2C | c.2270del p.N757Mfs*8 | Frame Shift Del (DEL) | VAF 55/129 reads (43%) | catalogued as COSV53791141; called by mutect2, pindel, varscan2
- H1-3 | c.455T>C p.I152T | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1398258407, COSV55096877; called by muse, mutect2, varscan2
- HACD3 | c.223C>A p.Q75K | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.715); catalogued as COSV56010846; called by muse, mutect2, varscan2
- HAS2 | c.1078C>T p.R360* | Nonsense Mutation (SNP) | VAF 23/58 reads (40%) | catalogued as COSV58262158; called by muse, mutect2, varscan2
- HCK | c.1303A>G p.T435A | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV52940361; called by muse, mutect2, varscan2
- HDAC1 | c.1402_1404del p.E468del | In Frame Del (DEL) | VAF 25/78 reads (32%) | catalogued as rs771427696; called by pindel, varscan2
- HDC | c.1825T>G p.S609A | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV51068355; called by muse, mutect2, varscan2
- HDGFL1 | c.377G>A p.G126D | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs1184843939, COSV57751246; called by muse, mutect2, varscan2
- HERC1 | c.13054C>T p.R4352C | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756796869, COSV71246008; called by muse, mutect2, varscan2
- HERC1 | c.6574C>T p.R2192C | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765707550, COSV71246010; called by mutect2, varscan2
- HIVEP2 | c.2821C>T p.R941C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50007055; called by muse, mutect2
- HKDC1 | c.385T>G p.Y129D | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.399); catalogued as COSV100664406; called by muse, mutect2, varscan2
- HMGB1 | c.131A>C p.K44T | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as COSV58104139; called by muse, mutect2
- HNRNPA3 | c.835G>A p.G279S | Missense Mutation (SNP) | VAF 16/486 reads (3%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.604); catalogued as rs1364922975, COSV66820990; called by muse, mutect2
- HOXA6 | c.484T>C p.Y162H | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99762123; called by muse, mutect2, varscan2
- HTR1B | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV64051116; called by muse, mutect2, varscan2
- HTR7 | c.995T>C p.I332T | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV53283125; called by muse, mutect2, varscan2
- HUNK | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 18/46 reads (39%) | catalogued as COSV54224820; called by muse, mutect2, varscan2
- HUWE1 | c.11726C>T p.A3909V | Missense Mutation (SNP) | VAF 22/27 reads (81%) | SIFT deleterious (0.02); PolyPhen benign (0.135); catalogued as COSV53335382; called by muse, mutect2, varscan2
- IGF2R | c.6560C>T p.A2187V | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.102); catalogued as rs201372819, COSV63482151; called by muse, mutect2, varscan2
- IGFBP4 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs745961147, COSV54096662; called by muse, mutect2, varscan2
- IGSF11 | c.877T>C p.C293R (on ENST00000393775 / NM_001015887.3; = p.C292R on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs759822063, COSV61165836; called by muse, mutect2, varscan2
- IGSF8 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1429452277, COSV100081537; called by muse, mutect2, varscan2
- IL17RA | c.1862C>T p.A621V | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs200201810, COSV60051418; called by muse, mutect2
- IL17RC | c.391G>A p.V131M (on ENST00000295981 / NM_153461.4; = p.V60M on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs201975186; called by muse, mutect2, varscan2
- INSR | c.1724A>G p.H575R | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV57157990; called by muse, mutect2, varscan2
- INTS2 | c.2615del p.P872Hfs*2 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | catalogued as rs753355779, COSV52155455; called by mutect2, pindel
- INTS6L | c.359del p.L120* | Frame Shift Del (DEL) | VAF 94/130 reads (72%) | catalogued as rs782242788; ClinVar: uncertain significance; called by mutect2, varscan2
- IPO8 | c.1756-1G>T p.X586_splice | Splice Site (SNP) | VAF 12/40 reads (30%) | catalogued as COSV56239734; called by muse, mutect2, varscan2
- IQCE | c.1616del p.K539Rfs*25 | Frame Shift Del (DEL) | VAF 18/47 reads (38%) | catalogued as rs759821884; called by mutect2, pindel*, varscan2
- IRF3 | c.782T>C p.V261A | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as COSV55862352, COSV55864487; called by muse, mutect2, varscan2
- ISG20L2 | c.865C>T p.L289F | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs958261300, COSV57459436; called by muse, mutect2, varscan2
- ITCH | c.1528C>A p.R510S (on ENST00000262650 / NM_001257137.3; = p.R469S on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52929513; called by muse, mutect2, varscan2
- ITGA11 | c.1528C>T p.R510C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); catalogued as COSV59875091; called by muse, mutect2, varscan2
- ITGA2B | c.2125_2127del p.K709del | In Frame Del (DEL) | VAF 3/22 reads (14%) | catalogued as rs1447740112; called by pindel, varscan2
- ITGA8 | c.843G>T p.Q281H | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.155); catalogued as COSV65224878; called by muse, mutect2
- ITGAM | c.2216T>C p.V739A (on ENST00000648685 / NM_001145808.2; = p.V738A on NM_000632.4) | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.369); catalogued as COSV54934170; called by muse, mutect2
- ITGB3 | c.1946del p.G649Efs*20 | Frame Shift Del (DEL) | VAF 14/39 reads (36%) | catalogued as COSV71384792; called by mutect2, pindel
- ITM2B | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as COSV66034865; called by muse, mutect2, varscan2
- ITPR3 | c.2387C>T p.P796L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs762693746, COSV65405956; called by muse, mutect2, varscan2
- JADE2 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV50911873; called by muse, mutect2, varscan2
- JAGN1 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 67/207 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs150551876; called by muse, mutect2, varscan2
- JMJD4 | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as rs372699883; called by muse, mutect2, varscan2
- JPT2 | c.196G>A p.G66S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50188513; called by mutect2, varscan2
- KALRN | c.2341-1G>T p.X781_splice | Splice Site (SNP) | VAF 18/51 reads (35%) | catalogued as COSV53753725; called by muse, mutect2, varscan2
- KCNC2 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as rs1191875389, COSV100128323; called by muse, mutect2, varscan2
- KCNG1 | c.811G>A p.V271M | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.658); catalogued as COSV65367972; called by muse, mutect2, varscan2
- KCNH2 | c.2348C>T p.S783F | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51126990; called by muse, mutect2, varscan2
- KCNH8 | c.2352dup p.N785Qfs*3 | Frame Shift Ins (INS) | VAF 24/78 reads (31%) | catalogued as rs760381227; called by mutect2, varscan2
- KCNK4 | c.703G>A p.V235M | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60453575; called by muse, mutect2, varscan2
- KCNK7 | c.96G>T p.E32D | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750933271, COSV58418409; called by muse, mutect2, varscan2
- KCNS3 | c.1198C>T p.L400F | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV58405408; called by muse, mutect2, varscan2
- KCTD19 | c.2301del p.V768Wfs*38 | Frame Shift Del (DEL) | VAF 24/80 reads (30%) | catalogued as rs759860142; called by mutect2, pindel
- KDM2B | c.1829G>A p.R610Q | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as COSV65638289; called by muse, mutect2, varscan2
- KDM5A | c.3982G>A p.V1328M | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs1336226402, COSV66990459; called by muse, varscan2
- KDM6B | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.187); catalogued as rs766290398, COSV54677991; called by muse, varscan2
- KDM6B | c.257T>C p.L86P | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); catalogued as COSV99640831; called by muse, mutect2, varscan2
- KDM8 | c.1204G>A p.V402M | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs141999943; called by muse, mutect2, varscan2
- KDR | c.3044G>A p.G1015D | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55758427; called by muse, varscan2
- KIAA0100 | c.2212G>A p.A738T | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV66490742; called by muse, mutect2, varscan2
- KIAA0319 | c.2425C>A p.Q809K | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT tolerated (0.87); PolyPhen benign (0.055); catalogued as COSV65496483; called by muse, mutect2, varscan2
- KIAA1210 | c.781T>G p.S261A | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.319); catalogued as COSV68175578; called by muse, mutect2, varscan2
- KIAA2026 | c.5452G>T p.G1818C | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV67353429; called by muse, mutect2, varscan2
- KIF13A | c.3486C>T p.D1162= | Splice Region (SNP) | VAF 14/33 reads (42%) | catalogued as COSV52443340; called by muse, varscan2
- KIF14 | c.1477A>G p.S493G | Missense Mutation (SNP) | VAF 61/165 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771409397, COSV100950658; called by muse, mutect2, varscan2
- KIF21A | c.3841C>T p.R1281C (on ENST00000361418 / NM_001378440.1; = p.R1268C on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as rs769601725, COSV62767577; called by muse, mutect2, varscan2
- KIF21B | c.4688C>G p.A1563G (on ENST00000422435 / NM_001252100.2; = p.A1550G on NM_017596.4) | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59752715; called by muse, mutect2, varscan2
- KLC2 | c.1567C>A p.L523I | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.053); catalogued as COSV57581624; called by muse, mutect2, varscan2
- KLRC1 | c.629T>C p.V210A | Missense Mutation (SNP) | VAF 481/897 reads (54%) | SIFT tolerated (0.16); PolyPhen benign (0.368); catalogued as COSV61724793; called by muse, mutect2, varscan2
- KMT2D | c.10943C>T p.P3648L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs758858726, COSV56412919; called by mutect2, varscan2
- KMT5B | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV58563850; called by muse, mutect2, varscan2
- KNOP1 | c.1237C>T p.Q413* | Nonsense Mutation (SNP) | VAF 24/52 reads (46%) | catalogued as COSV54926738; called by muse, mutect2, varscan2
- KRIT1 | c.835A>G p.T279A | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV60666876; called by muse, mutect2
- KRT34 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs760710478, COSV67449280; called by muse, mutect2, varscan2
- KRT73 | c.320T>C p.V107A | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59837979; called by muse, mutect2, varscan2
- KRT76 | c.1666G>A p.G556S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750741913, COSV60119224; called by muse, mutect2, varscan2
- KRTAP13-4 | c.470A>G p.Q157R | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61878556; called by muse, mutect2, varscan2
- KRTAP15-1 | c.283C>A p.L95I | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as COSV61876948, COSV61877024; called by muse, mutect2, varscan2
- KRTAP5-5 | c.281del p.G94Afs*157 | Frame Shift Del (DEL) | VAF 20/71 reads (28%) | catalogued as COSV68784656, COSV68785101; called by mutect2, pindel, varscan2
- LAMA5 | c.7223G>A p.R2408H | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs575134003, COSV53353321; called by muse, mutect2, varscan2
- LARP1 | c.906del p.T303Pfs*23 (on ENST00000518297 / NM_033551.3; = p.T226Pfs*23 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 26/52 reads (50%) | catalogued as rs769338468, COSV60425051; called by mutect2, varscan2
- LARP1B | c.2129A>C p.Q710P | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV52794660; called by muse, mutect2, varscan2
- LEKR1 | c.*844A>G | Splice Region (SNP) | VAF 112/285 reads (39%) | catalogued as COSV62960667; called by muse, mutect2, varscan2
- LHB | c.347G>A p.S116N | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.062); catalogued as COSV55484306; called by muse, mutect2, varscan2
- LHX5 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 82/153 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV55662009; called by muse, mutect2, varscan2
- LIG1 | c.422G>A p.S141N | Missense Mutation (SNP) | VAF 67/145 reads (46%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV99618589; called by muse, mutect2, varscan2
- LIMCH1 | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 24/84 reads (29%) | catalogued as rs1001272864, COSV58274062; called by muse, mutect2, varscan2
- LMNB2 | c.1629dup p.S544Lfs*23 | Frame Shift Ins (INS) | VAF 10/38 reads (26%) | catalogued as rs776267567; called by mutect2, varscan2
- LMO7 | c.1166G>A p.R389H (on ENST00000357063; = p.R119H on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs1211852622, COSV58530439; called by muse, mutect2, varscan2
- LMX1B | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62738159; called by muse, mutect2, varscan2
- LONRF1 | c.1483G>A p.G495R | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1175133976, COSV68035967; called by muse, mutect2, varscan2
- LONRF3 | c.817+1G>A p.X273_splice | Splice Site (SNP) | VAF 17/21 reads (81%) | catalogued as COSV59150032; called by muse, mutect2, varscan2
- LRFN2 | c.1888G>T p.G630W | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.397); catalogued as COSV57824115; called by muse, mutect2, varscan2
- LRP1 | c.2147T>C p.V716A | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.097); catalogued as COSV99674739; called by muse, mutect2
- LRP1 | c.10201G>T p.D3401Y | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54502593; called by muse, mutect2, varscan2
- LRP1B | c.9629C>G p.P3210R | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.289); catalogued as COSV101253571; called by muse, mutect2
- LRRC4B | c.2132C>T p.T711M | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65349268; called by muse, mutect2, varscan2
- LRRC4B | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV65349270; called by muse, mutect2, varscan2
- LRRC75B | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs369950570, COSV50638165; called by muse, mutect2, varscan2
- LRRIQ3 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.044); catalogued as COSV63041387; called by muse, mutect2, varscan2
- LSP1 | c.322del p.Q108Sfs*31 | Frame Shift Del (DEL) | VAF 26/68 reads (38%) | catalogued as rs752018434; called by pindel, varscan2
- LTF | c.1963T>C p.S655P | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV51605751; called by muse, mutect2, varscan2
- LUZP1 | c.3005T>C p.V1002A | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as COSV100034546; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs908403443, COSV65442557; called by muse, varscan2
- LY6G6F-LY6G6D | c.579G>T p.R193S | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.457); catalogued as COSV65442563, COSV65443230; called by muse, varscan2
- LZTR1 | c.1125G>T p.K375N | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV99301390, COSV99301843; called by muse, mutect2, varscan2
- LZTS3 | c.1886G>A p.R629H (on ENST00000329152; = p.R583H on NM_001282533.2) | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs769528128, COSV53904306; called by muse, mutect2, varscan2
- MACF1 | c.2381A>G p.D794G | Missense Mutation (SNP) | VAF 15/56 reads (27%) | catalogued as COSV58360513; called by muse, mutect2, varscan2
- MAGI3 | c.4072dup p.I1358Nfs*6 | Frame Shift Ins (INS) | VAF 30/76 reads (39%) | catalogued as rs1278102315; called by mutect2, varscan2
- MAGT1 | c.952C>T p.L318F (on ENST00000618282 / NM_001367916.1; = p.L350F on NM_032121.5) | Missense Mutation (SNP) | VAF 188/261 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as COSV63780902; called by muse, mutect2, varscan2
- MAML1 | c.1402C>T p.P468S | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs763800343, COSV52983121; called by muse, mutect2, varscan2
- MAML2 | c.1953_1955dup p.Q665dup | In Frame Ins (INS) | VAF 21/90 reads (23%) | catalogued as rs768485776; called by mutect2, varscan2
- MAP1S | c.1369C>T p.P457S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV100140861; called by muse, mutect2
- MAP3K6 | c.1737C>T p.S579= | Splice Region (SNP) | VAF 4/13 reads (31%) | catalogued as rs374727579; called by muse, mutect2, varscan2
- MAP3K6 | c.511G>A p.V171I | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs146245417; called by muse, mutect2, varscan2
- MAP3K9 | c.1444C>T p.R482W | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1262960434, COSV67119994; called by muse, mutect2, varscan2
- MAPRE2 | c.499T>C p.Y167H | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV55817485; called by muse, mutect2, varscan2
- MAPRE2 | c.920C>T p.T307I | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.266); catalogued as rs919525609, COSV55817513; called by muse, mutect2, varscan2
- MARK3 | c.1723G>A p.A575T | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.079); catalogued as rs767907025, COSV53506553; called by muse, mutect2, varscan2
- MASTL | c.692C>A p.P231H | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.106); catalogued as COSV60909538; called by muse, mutect2, varscan2
- MASTL | c.1372dup p.I458Nfs*5 | Frame Shift Ins (INS) | VAF 18/62 reads (29%) | catalogued as rs780698479; called by mutect2, varscan2
- MATN1 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.27); catalogued as rs1410669396, COSV65650119; called by muse, mutect2, varscan2
- MCM6 | c.1855C>T p.R619* | Nonsense Mutation (SNP) | VAF 15/40 reads (38%) | catalogued as rs945901290, COSV51464940; called by muse, mutect2, varscan2
- MCMBP | c.327+2T>C p.X109_splice | Splice Site (SNP) | VAF 31/110 reads (28%) | catalogued as COSV63508535; called by muse, mutect2, varscan2
- MCOLN3 | c.137dup p.M47Hfs*5 | Frame Shift Ins (INS) | VAF 15/39 reads (38%) | catalogued as rs772812591; called by mutect2, varscan2
- MDN1 | c.12713G>A p.R4238Q | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs771870100, COSV65517464; called by muse, mutect2, varscan2
- ME1 | c.1696A>G p.I566V | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV63837668; called by muse, mutect2, varscan2
- MEAK7 | c.530-2A>G p.X177_splice | Splice Site (SNP) | VAF 6/27 reads (22%) | catalogued as COSV59143232; called by mutect2, varscan2
- MECOM | c.1839del p.G614Efs*30 (on ENST00000468789 / NM_001105078.4; = p.G802Efs*30 on NM_004991.4) | Frame Shift Del (DEL) | VAF 26/82 reads (32%) | catalogued as rs773080349; called by mutect2, pindel, varscan2
- MED16 | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV99515192; called by muse, mutect2
- MED24 | c.1619T>C p.L540P | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV100673019; called by muse, mutect2, varscan2
- MFN1 | c.845T>C p.F282S | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54938097; called by muse, mutect2, varscan2
- MFSD1 | c.1064C>A p.P355H | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51839153; called by muse, mutect2, varscan2
- MFSD12 | c.323T>C p.F108S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62597256; called by muse, mutect2, varscan2
- MFSD14A | c.806del p.L269Yfs*6 | Frame Shift Del (DEL) | VAF 58/160 reads (36%) | catalogued as rs780635289; called by mutect2, varscan2
- MGAT4C | c.541A>G p.I181V | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV59830096; called by muse, mutect2, varscan2
- MGRN1 | c.1563G>T p.Q521H | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.736); catalogued as COSV52148470; called by muse, mutect2, varscan2
- MIA2 | c.176del p.L59Cfs*22 | Frame Shift Del (DEL) | VAF 88/346 reads (25%) | catalogued as rs769553721, COSV54495286; called by mutect2, varscan2
- MISP | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs1052701345, COSV53118834; called by muse, mutect2, varscan2
- MKI67 | c.9241G>C p.D3081H | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.648); catalogued as COSV64072675; called by muse, mutect2, varscan2
- MKRN3 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); catalogued as COSV58808640; called by muse, mutect2, varscan2
- MMADHC | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs1434979492, COSV57573106; called by muse, mutect2, varscan2
- MMP8 | c.707A>C p.Y236S | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV52631107; called by muse, mutect2, varscan2
- MPDZ | c.3119G>C p.G1040A | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100056262; called by mutect2, varscan2
- MPRIP | c.1640A>G p.E547G | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57925601; called by muse, mutect2, varscan2
- MRPL54 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772250551, COSV57519246; called by muse, mutect2, varscan2
- MRTFA | c.1031del p.P344Rfs*93 | Frame Shift Del (DEL) | VAF 26/114 reads (23%) | catalogued as rs1569254400, COSV62933307; called by mutect2, pindel
- MST1 | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56532206; called by muse, mutect2, varscan2
- MTA1 | c.232G>A p.G78S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs782756415, COSV58755749; called by muse, mutect2, varscan2
- MUC5B | c.5525A>G p.Q1842R | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.623); catalogued as rs771855599, COSV101500067; called by muse, mutect2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | catalogued as rs764857791; called by mutect2, varscan2
- MYBBP1A | c.3176T>C p.V1059A | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as COSV99625487; called by muse, mutect2, varscan2
- MYBPH | c.14del p.N5Tfs*73 | Frame Shift Del (DEL) | VAF 15/48 reads (31%) | catalogued as rs752878638; called by mutect2, pindel, varscan2
- MYCBP2 | c.3595T>G p.F1199V (on ENST00000357337; = p.F1237V on NM_015057.5) | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62010808; called by muse, mutect2, varscan2
- MYH15 | c.40del p.W14Gfs*5 | Frame Shift Del (DEL) | VAF 29/78 reads (37%) | catalogued as rs752868848; called by mutect2, pindel, varscan2
- MYH6 | c.2219G>A p.S740N | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV62448041; called by muse, mutect2, varscan2
- MYH6 | c.386A>G p.K129R | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV100676335; called by muse, mutect2, varscan2
- MYH7 | c.4468G>A p.E1490K | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62516473; called by muse, mutect2, varscan2
- MYH7 | c.3500G>A p.R1167H | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766412659, COSV100805754; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH8 | c.1732G>A p.A578T | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.382); catalogued as rs758179709, COSV67960114; called by muse, mutect2, varscan2
- MYH9 | c.5174G>A p.R1725Q | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs993895986, COSV53382234; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO10 | c.3500A>G p.D1167G | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.491); catalogued as COSV99944824; called by muse, mutect2, varscan2
- MYO18B | c.1750G>A p.E584K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59126039, COSV59130318; called by muse, mutect2, varscan2
- MYO1E | c.1054C>T p.R352W | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1477519647, COSV55682732; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO1G | c.2545G>T p.A849S | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.72); PolyPhen benign (0.017); catalogued as COSV51853191, COSV51856786; called by muse, mutect2, varscan2
- MZF1 | c.2138A>G p.D713G | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.765); catalogued as rs1455165967, COSV53040717; called by muse, mutect2, varscan2
- NAA25 | c.1710dup p.H571Sfs*21 | Frame Shift Ins (INS) | VAF 26/137 reads (19%) | catalogued as rs1566006956; called by pindel, varscan2
- NAIF1 | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs904677253, COSV100895720; called by muse, mutect2, varscan2
- NBEA | c.4591A>T p.I1531F | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV59761863; called by muse, mutect2, varscan2
- NBEAL2 | c.5132G>A p.R1711H | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs1272526590, COSV52754420; called by muse, mutect2, varscan2
- NDN | c.877C>T p.R293* | Nonsense Mutation (SNP) | VAF 14/22 reads (64%) | catalogued as COSV59358413, COSV59358508; called by muse, mutect2
- NEK5 | c.1504del p.T502Pfs*4 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | catalogued as rs1189669701, COSV62882362; called by mutect2, pindel, varscan2
- NELFE | c.787A>G p.T263A | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV100952620; called by muse, mutect2, varscan2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 9/30 reads (30%) | catalogued as rs759081520; called by mutect2, pindel, varscan2
- NFASC | c.2815G>A p.A939T | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.093); catalogued as COSV58359282; called by muse, mutect2, varscan2
- NFIA | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs761025450, COSV63607764; called by muse, mutect2, varscan2
- NIM1K | c.211A>T p.I71L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV58139580; called by muse, mutect2, varscan2
- NIPBL | c.8221G>A p.A2741T | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.07); catalogued as COSV56942815; called by muse, mutect2, varscan2
- NKX2-5 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV61298347, COSV61299339; called by muse, mutect2, varscan2
- NLGN4Y | c.1222G>A p.G408S | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.233); catalogued as COSV100196434; called by muse, mutect2, varscan2
- NLRP14 | c.710G>A p.W237* | Nonsense Mutation (SNP) | VAF 25/61 reads (41%) | catalogued as COSV55064286; called by muse, mutect2, varscan2
- NLRP2 | c.3113del p.N1038Tfs*4 | Frame Shift Del (DEL) | VAF 17/56 reads (30%) | catalogued as rs745782532; called by mutect2, pindel, varscan2
- NLRP7 | c.1498G>A p.V500I | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV60171302; called by muse, mutect2, varscan2
- NMNAT3 | c.619C>T p.R207* (on ENST00000296202 / NM_001320512.1; = p.R170* on NM_178177.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 32/88 reads (36%) | catalogued as rs931361937, COSV56155005; called by muse, mutect2, varscan2
- NOP14 | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs143842679; called by muse, mutect2, varscan2
- NOS1 | c.146G>T p.G49V | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV57607138; called by muse, mutect2, varscan2
- NOTUM | c.1409T>C p.M470T | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV101293758, COSV68826180; called by muse, mutect2
- NPC1 | c.782C>T p.T261M | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs374169117; called by muse, varscan2
- NR2F1 | c.1112T>G p.L371R | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59067584; called by muse, mutect2, varscan2
- NRAP | c.1795G>A p.D599N (on ENST00000359988 / NM_001322945.2; = p.D564N on NM_006175.4) | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752564116, COSV63488605; called by muse, mutect2, varscan2
- NRXN2 | c.4969A>G p.M1657V | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV55447640; called by muse, mutect2, varscan2
- NT5C3B | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 33/66 reads (50%) | catalogued as COSV53172651; called by muse, mutect2, varscan2
- NTAQ1 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs755433395, COSV54873724; called by muse, mutect2, varscan2
- NUFIP1 | c.526del p.C176Vfs*27 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | catalogued as rs1566064574; called by mutect2, varscan2
- NUP133 | c.1223C>T p.T408M | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs777394053, COSV54568432; called by muse, mutect2, varscan2
- NUP205 | c.6004C>T p.R2002C | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760991716, COSV99606559; called by mutect2, varscan2
- NUP210 | c.3785C>A p.P1262H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.095); catalogued as COSV54402760; called by muse, mutect2, varscan2
- NUP214 | c.649G>A p.V217I | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.85); catalogued as COSV100845165; called by muse, mutect2, varscan2
- NUP214 | c.754T>C p.Y252H | Missense Mutation (SNP) | VAF 60/194 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as COSV63907772; called by muse, mutect2, varscan2
- OBSCN | c.12190C>T p.R4064C | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs952042125, COSV52742967; called by muse, mutect2, varscan2
- OBSCN | c.20977del p.A6993Pfs*79 | Frame Shift Del (DEL) | VAF 15/50 reads (30%) | catalogued as rs762005098; called by mutect2, pindel
- OCIAD1 | c.494G>A p.S165N | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV51900107; called by muse, mutect2, varscan2
- OLFM1 | c.815G>A p.R272H (on ENST00000371793 / NM_001282611.2; = p.R254H on NM_014279.5) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1325605984, COSV53276531; called by muse, mutect2, varscan2
- OLFML2B | c.2001del p.L668Sfs*57 | Frame Shift Del (DEL) | VAF 31/97 reads (32%) | catalogued as COSV54194578; called by mutect2, pindel, varscan2
- OPLAH | c.3419T>C p.M1140T | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1554757845, COSV101470731; called by muse, mutect2
- OR10R2 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.491); catalogued as rs772100056, COSV63768501; called by muse, mutect2, varscan2
- OR10Z1 | c.535del p.C179Vfs*7 | Frame Shift Del (DEL) | VAF 42/105 reads (40%) | catalogued as rs755391413; called by mutect2, pindel, varscan2
- OR2AG2 | c.91T>A p.F31I | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1295899038, COSV58454631; called by muse, mutect2, varscan2
- OR2B11 | c.800del p.P267Lfs*18 | Frame Shift Del (DEL) | VAF 19/65 reads (29%) | catalogued as COSV59511126; called by mutect2, pindel, varscan2
- OR4K2 | c.197T>G p.L66R | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV53848201; called by muse, mutect2, varscan2
- OR56B1 | c.96G>A p.W32* | Nonsense Mutation (SNP) | VAF 29/71 reads (41%) | catalogued as COSV100402569, COSV57722537; called by muse, mutect2, varscan2
- OR8K3 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.02); catalogued as COSV57130815; called by muse, mutect2, varscan2
- ORC1 | c.1364C>T p.T455M | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.346); catalogued as rs753121823, COSV65363354; called by muse, mutect2, varscan2
- OS9 | c.1883C>T p.P628L | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs754364285, COSV99222358; called by mutect2, varscan2
- OSGEP | c.890C>A p.A297E | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV52831370; called by muse, mutect2, varscan2
- OTUD7A | c.1420del p.V474Cfs*62 (on ENST00000307050 / NM_001382637.1; = p.V467Cfs*62 on NM_130901.3) | Frame Shift Del (DEL) | VAF 6/15 reads (40%) | catalogued as COSV61036088; called by mutect2, varscan2
- PADI1 | c.1992A>T p.*664Cext*13 | Nonstop Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as COSV64934000; called by muse, mutect2, varscan2
- PAPLN | c.3817G>A p.A1273T (on ENST00000554301; = p.A1246T on NM_173462.4) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as rs747204977, COSV53713335; called by muse, mutect2, varscan2
- PAPPA | c.578C>A p.P193Q | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769143108, COSV60277769; called by muse, mutect2, varscan2
- PARP12 | c.1555C>T p.R519C | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as rs566167926, COSV54932292; called by muse, mutect2
- PARP14 | c.5248C>T p.H1750Y | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV71734146; called by muse, mutect2, varscan2
- PAXIP1 | c.2626C>T p.P876S | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.976); catalogued as COSV68184831; called by muse, mutect2, varscan2
- PCDH10 | c.1654del p.Q552Rfs*13 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | catalogued as COSV52091732; called by mutect2, pindel, varscan2
- PCDHA7 | c.2063G>A p.G688D | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.013); catalogued as COSV65334938; called by muse, mutect2
- PCDHB10 | c.61del p.W21Gfs*15 | Frame Shift Del (DEL) | VAF 30/160 reads (19%) | catalogued as rs782003738; called by pindel, varscan2
- PCDHB3 | c.1975C>T p.H659Y | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); catalogued as rs1160123947, COSV99164268; called by muse, mutect2
- PCDHGB1 | c.1705G>A p.A569T | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.313); catalogued as COSV53902592; called by muse, mutect2, varscan2
- PCDHGB2 | c.892dup p.T298Nfs*9 | Frame Shift Ins (INS) | VAF 17/58 reads (29%) | catalogued as rs758957504; called by mutect2, pindel, varscan2
- PCDHGB2 | c.1954C>T p.P652S | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV53902626; called by muse, mutect2, varscan2
- PCLO | c.7325del p.K2442Sfs*2 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as COSV61618667; called by mutect2, varscan2
- PCNT | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.648); catalogued as rs1208617321, COSV100855105; called by muse, mutect2
- PCSK4 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as rs775454627, COSV52012379; called by muse, mutect2, varscan2
- PDE5A | c.2001A>G p.R667= | Splice Region (SNP) | VAF 48/174 reads (28%) | catalogued as COSV53345741; called by muse, mutect2, varscan2
- PDE6A | c.2432del p.A811Gfs*10 | Frame Shift Del (DEL) | VAF 19/84 reads (23%) | catalogued as COSV54924794, COSV99677891; called by mutect2, pindel, varscan2
- PDHA2 | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.1); catalogued as rs550119402, COSV54777272; called by muse, mutect2, varscan2
- PDHX | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs768910663, COSV57164207, COSV57164870; called by muse, mutect2, varscan2
- PDLIM7 | c.1169G>A p.R390Q | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as rs535394998, COSV63080261; called by muse, mutect2, varscan2
- PDPN | c.343G>A p.G115R (on ENST00000621990; = p.G191R on NM_006474.4) | Missense Mutation (SNP) | VAF 48/173 reads (28%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.948); catalogued as COSV99611241; called by muse, varscan2
- PDS5A | c.2088A>C p.E696D | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.389); catalogued as COSV57822684; called by muse, mutect2, varscan2
- PDS5B | c.2788C>A p.L930I | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100220581; called by muse, mutect2, varscan2
- PDZD2 | c.347T>C p.V116A | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56851319; called by muse, mutect2, varscan2
- PELP1 | c.1478C>T p.A493V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV52585845; called by muse, mutect2, varscan2
- PFKFB3 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 11/53 reads (21%) | PolyPhen benign (0.034); catalogued as rs140784797; called by muse, mutect2, varscan2
- PFKFB3 | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 12/47 reads (26%) | PolyPhen benign (0.052); catalogued as rs750254792, COSV57986964; called by muse, mutect2, varscan2
- PGLYRP2 | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52991413; called by muse, mutect2, varscan2
- PHETA1 | c.328C>A p.R110S | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100825313; called by muse, mutect2, varscan2
- PHF13 | c.830G>A p.C277Y | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50010553; called by muse, mutect2, varscan2
- PHLPP1 | c.3316G>T p.E1106* | Nonsense Mutation (SNP) | VAF 46/118 reads (39%) | catalogued as COSV53024251, COSV99407524; called by muse, mutect2, varscan2
- PI3 | c.180A>C p.K60N | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99714118; called by muse, mutect2, varscan2
- PIH1D1 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as rs564302977, COSV51806370; called by muse, mutect2, varscan2
- PIP4K2A | c.941dup p.D315Rfs*2 | Frame Shift Ins (INS) | VAF 14/32 reads (44%) | catalogued as rs755454854; called by mutect2, varscan2
- PITHD1 | c.247A>G p.T83A | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV99862082; called by muse, mutect2, varscan2
- PIWIL2 | c.2288G>A p.S763N | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV63249856; called by muse, mutect2, varscan2
- PKD1 | c.5492C>T p.T1831M | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.322); catalogued as rs757842622, COSV99237323; called by muse, mutect2, varscan2
- PKD1L1 | c.3050A>C p.Y1017S | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.294); catalogued as COSV56958437; called by muse, mutect2, varscan2
- PKN1 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs371928270; called by muse, mutect2, varscan2
- PLA2G4E | c.2149C>T p.R717* | Nonsense Mutation (SNP) | VAF 30/56 reads (54%) | catalogued as rs772442758, COSV68148900; called by muse, mutect2, varscan2
- PLAAT4 | c.483del p.A162Rfs*56 | Frame Shift Del (DEL) | VAF 53/71 reads (75%) | catalogued as rs745860467; called by mutect2, varscan2
- PLD1 | c.2722A>G p.I908V | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs1335091742, COSV60565552; called by muse, mutect2, varscan2
- PLEKHA7 | c.2275C>A p.H759N | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as COSV63043833; called by muse, mutect2, varscan2
- PLEKHH1 | c.55C>A p.L19M | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.241); catalogued as COSV61280396; called by muse, mutect2, varscan2
- PLK1 | c.596C>T p.T199I | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55620171; called by muse, mutect2, varscan2
- PLXNA4 | c.5603T>C p.L1868P | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58106461, COSV58162345; called by muse, mutect2, varscan2
- PLXNC1 | c.4585G>A p.V1529I | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs150282069; called by muse, mutect2, varscan2
- POFUT1 | c.343A>G p.T115A | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.73); PolyPhen benign (0.029); catalogued as COSV65260021; called by muse, mutect2, varscan2
- POGZ | c.2235-1G>T p.X745_splice | Splice Site (SNP) | VAF 15/41 reads (37%) | catalogued as COSV55032491; called by muse, mutect2, varscan2
- POLA1 | c.2676T>C p.D892= | Splice Region (SNP) | VAF 99/147 reads (67%) | catalogued as rs1470460270, COSV66883774; called by muse, varscan2
- POLD1 | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.189); catalogued as rs762330164, COSV70954244; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLR2J | c.52_53+1del p.X18_splice | Splice Site (DEL) | VAF 14/85 reads (16%) | catalogued as rs776032800; called by pindel, varscan2
- POLR3E | c.1966A>T p.I656F | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.163); catalogued as COSV55398985; called by muse, mutect2
- POP4 | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs753961498, COSV55675838; called by muse, varscan2
- PPARGC1A | c.2314G>T p.D772Y | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV53524693; called by muse, mutect2, varscan2
- PPFIA3 | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.048); catalogued as rs1184447820, COSV61949369; called by muse, mutect2, varscan2
- PPL | c.3664C>T p.R1222* | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | catalogued as rs766474309, COSV52165830; called by muse, mutect2, varscan2
- PPP6R1 | c.170T>C p.M57T | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV101336948; called by muse, mutect2
- PPTC7 | c.658A>G p.T220A | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.105); catalogued as COSV62825761; called by muse, mutect2, varscan2
- PRCP | c.1378C>T p.R460C | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372175092, COSV100475949; called by muse, mutect2, varscan2
- PRKAR2A | c.580A>G p.T194A | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV55550768; called by muse, mutect2, varscan2
- PRKRA | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.539); catalogued as COSV57867835; called by muse, mutect2, varscan2
- PRR35 | c.430G>A p.V144M | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.222); catalogued as COSV99551869; called by muse, mutect2, varscan2
- PRRG3 | c.494dup p.R166Qfs*14 | Frame Shift Ins (INS) | VAF 12/22 reads (55%) | catalogued as rs748526759; called by mutect2, varscan2
- PRSS37 | c.547G>C p.V183L | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1241697707, COSV63339029, COSV63339782; called by muse, mutect2, varscan2
- PRUNE2 | c.9109A>G p.I3037V | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99795907; called by muse, mutect2, varscan2
- PSMD1 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV58076370; called by muse, mutect2, varscan2
- PSMD4 | c.101A>G p.N34S | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.646); catalogued as rs768592153, COSV64393069; called by muse, mutect2, varscan2
- PSME4 | c.5413del p.T1805Pfs*69 | Frame Shift Del (DEL) | VAF 51/82 reads (62%) | catalogued as COSV101122574; called by mutect2, varscan2
- PTGDR2 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.054); catalogued as COSV57124512; called by muse, mutect2, varscan2
- PTOV1 | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.022); catalogued as rs771781769, COSV55586427; called by muse, mutect2, varscan2
- PTPN14 | c.2711T>C p.L904P | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65281635; called by muse, mutect2, varscan2
- PTPRE | c.1121G>A p.R374H | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54546674; called by muse, mutect2, varscan2
- PUM2 | c.125A>G p.D42G | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV57578041; called by muse, mutect2, varscan2
- PZP | c.4389G>C p.E1463D | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.787); catalogued as COSV54354834; called by muse, mutect2, varscan2
- R3HDM2 | c.2737dup p.D913Gfs*7 | Frame Shift Ins (INS) | VAF 9/22 reads (41%) | catalogued as rs767243487; called by mutect2, varscan2
- RAB3GAP2 | c.2810G>A p.G937D | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV62782331; called by muse, mutect2, varscan2
- RABEP1 | c.648+2T>C p.X216_splice | Splice Site (SNP) | VAF 4/38 reads (11%) | catalogued as COSV52582805; called by mutect2, varscan2
- RABGEF1 | c.326G>A p.R109H (on ENST00000439720 / NM_001287061.2; = p.R96H on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/185 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.517); catalogued as rs761200639, COSV53160750; called by muse, mutect2, varscan2
- RADIL | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs774590739, COSV68199307; called by muse, mutect2, varscan2
- RAE1 | c.91-2A>G p.X31_splice | Splice Site (SNP) | VAF 26/77 reads (34%) | catalogued as COSV64797763; called by muse, mutect2, varscan2
- RAI1 | c.3103del p.Q1035Rfs*29 | Frame Shift Del (DEL) | VAF 5/17 reads (29%) | catalogued as rs774789734; called by mutect2, pindel, varscan2
- RARB | c.832A>G p.T278A (on ENST00000383772 / NM_001290216.2; = p.T271A on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.348); catalogued as COSV51968832; called by muse, mutect2, varscan2
- RASSF4 | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs137923619, COSV58487285; called by muse, mutect2, varscan2
- RASSF5 | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as COSV62424408; called by muse, mutect2, varscan2
- RAVER2 | c.2055A>T p.L685F (on ENST00000294428 / NM_001366165.1; = p.L672F on NM_018211.4) | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.041); catalogued as rs759218839, COSV53805154; called by muse, mutect2, varscan2
- RBBP8 | c.1071del p.K357Nfs*3 | Frame Shift Del (DEL) | VAF 41/83 reads (49%) | catalogued as rs754547584, COSV59093143; ClinVar: uncertain significance; called by mutect2, varscan2
- RBM17 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as rs1219714754, COSV65913631; called by muse, varscan2
- RBM27 | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as rs1287380103, COSV54587578; called by muse, mutect2, varscan2
- RBM4B | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.22); PolyPhen benign (0.091); catalogued as rs12224194, COSV59496451; called by muse, mutect2, varscan2
- RDH5 | c.56G>A p.R19K | Missense Mutation (SNP) | VAF 57/123 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.293); catalogued as rs370781214; called by muse, mutect2, varscan2
- RECK | c.1838G>A p.R613H | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as rs772507584, COSV65034653; called by muse, mutect2, varscan2
- REEP4 | c.303+2T>C p.X101_splice | Splice Site (SNP) | VAF 13/28 reads (46%) | catalogued as COSV57941493; called by muse, mutect2, varscan2
- RELL2 | c.646A>G p.M216V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV51836596; called by muse, mutect2, varscan2
- REPS1 | c.1158G>T p.E386D | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV57808820; called by muse, mutect2, varscan2
- RGL4 | c.205T>C p.W69R | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV51943168; called by muse, mutect2, varscan2
- RIF1 | c.5751G>T p.M1917I | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV54612675; called by muse, mutect2, varscan2
- RIMS1 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53440102; called by muse, varscan2
- RIMS1 | c.2520A>C p.E840D | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV99324631; called by muse, mutect2
- RINT1 | c.1477T>C p.Y493H | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57557481; called by muse, mutect2, varscan2
- RNF123 | c.3665A>G p.D1222G | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100246458; called by muse, mutect2, varscan2
- RNF20 | c.859C>T p.R287* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as rs759230038, COSV66660402; called by muse, mutect2, varscan2
- RNF213 | c.15065del p.C5022Lfs*7 | Frame Shift Del (DEL) | VAF 9/56 reads (16%) | catalogued as COSV60390709; called by mutect2, pindel, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 10/20 reads (50%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPL27 | c.170T>C p.M57T | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.305); catalogued as COSV53814530, COSV53815591; called by muse, mutect2, varscan2
- RPS2 | c.267+2T>C p.X89_splice | Splice Site (SNP) | VAF 7/20 reads (35%) | catalogued as COSV51909472; called by muse, mutect2, varscan2
- RPS6KA1 | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs779751417, COSV65175249; called by muse, mutect2, varscan2
- RPS6KC1 | c.2640G>T p.K880N | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.936); catalogued as rs767587139, COSV65297275; called by muse, mutect2, varscan2
- RPUSD1 | c.524A>C p.Q175P | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99135625; called by muse, mutect2, varscan2
- RTP1 | c.529G>A p.V177M | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as rs760071149, COSV56617728; called by muse, mutect2, varscan2
- RWDD2B | c.554T>A p.L185H | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV54501115; called by muse, mutect2, varscan2
- RYR1 | c.7697C>T p.A2566V | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.98); catalogued as rs1285547623, COSV62089550; called by muse, mutect2, varscan2
- RYR2 | c.9794G>T p.C3265F | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.526); catalogued as COSV63660217; called by muse, mutect2, varscan2
- RYR3 | c.9482C>T p.T3161I (on ENST00000389232; = p.T3162I on NM_001036.6) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66778775; called by muse, mutect2, varscan2
- SATB1 | c.1554G>T p.K518N | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58667641; called by muse, mutect2, varscan2
- SCAP | c.3379A>G p.I1127V | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.059); catalogued as rs760342147, COSV99650255; called by muse, varscan2
- SCAPER | c.3647C>T p.A1216V | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.167); catalogued as COSV57734399; called by muse, mutect2, varscan2
- SCG2 | c.1630G>T p.E544* | Nonsense Mutation (SNP) | VAF 33/75 reads (44%) | catalogued as COSV59539092; called by muse, mutect2, varscan2
- SCG3 | c.1328A>G p.Q443R | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV99590728; called by muse, mutect2
- SCRIB | c.3442G>A p.D1148N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs138813890; called by muse, mutect2, varscan2
- SDHA | c.656A>G p.Y219C | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs756877901, COSV53765557; called by muse, mutect2, varscan2
- SELE | c.422-2A>G p.X141_splice | Splice Site (SNP) | VAF 16/68 reads (24%) | catalogued as COSV60973999; called by muse, mutect2, varscan2
- SEMA3E | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 92/270 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV57080425; called by muse, mutect2, varscan2
- SENP8 | c.476A>C p.N159T | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61767730; called by muse, mutect2, varscan2
- SETD4 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.213); catalogued as rs751127123, COSV59771240; called by muse, mutect2, varscan2
- SETDB2 | c.840T>A p.Y280* | Nonsense Mutation (SNP) | VAF 11/31 reads (35%) | catalogued as COSV99320549; called by muse, mutect2
- SFSWAP | c.527del p.N176Mfs*6 | Frame Shift Del (DEL) | VAF 18/60 reads (30%) | catalogued as rs1566002834; called by mutect2, pindel, varscan2
- SFTPD | c.976T>C p.Y326H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100954484; called by muse, mutect2, varscan2
- SGK2 | c.30A>C p.K10N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV100414570, COSV58312550; called by muse, mutect2, varscan2
- SH3BP2 | c.1103del p.P368Qfs*21 | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | catalogued as COSV62554014; called by mutect2, pindel, varscan2
- SHANK3 | c.3836C>A p.P1279Q | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53183678; called by muse, mutect2, varscan2
- SHC1 | c.1087del p.V363Wfs*2 (on ENST00000368445 / NM_183001.5; = p.V253Wfs*2 on NM_003029.5) | Frame Shift Del (DEL) | VAF 15/33 reads (45%) | catalogued as rs746556543; called by mutect2, varscan2
- SHF | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52049411; called by muse, mutect2, varscan2
- SHROOM3 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs777596931, COSV99933679; called by muse, mutect2, varscan2
- SI | c.4839T>C p.H1613= | Splice Region (SNP) | VAF 41/109 reads (38%) | catalogued as COSV52266802; called by muse, mutect2, varscan2
- SIMC1 | c.564C>A p.C188* (on ENST00000443967 / NM_001308196.1; = p.C207* on NM_001308195.2) | Nonsense Mutation (SNP) | VAF 39/72 reads (54%) | catalogued as COSV57900331; called by muse, mutect2, varscan2
- SIN3B | c.1243G>A p.G415R | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56131333; called by muse, mutect2, varscan2
- SKIDA1 | c.1597T>C p.Y533H | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV71610454; called by muse, mutect2, varscan2
- SLC12A8 | c.1075A>G p.T359A | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV58863245; called by muse, mutect2, varscan2
- SLC13A1 | c.411G>A p.W137* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as COSV52008309; called by muse, mutect2
- SLC17A6 | c.747C>T p.Y249= | Splice Region (SNP) | VAF 42/126 reads (33%) | catalogued as rs753049319, COSV54133640; called by muse, mutect2, varscan2
- SLC27A3 | c.1810C>T p.H604Y (on ENST00000271857; = p.H476Y on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (1); PolyPhen possibly damaging (0.669); catalogued as rs745383068, COSV55162205; called by muse, mutect2, varscan2
- SLC34A1 | c.1188del p.F397Sfs*16 | Frame Shift Del (DEL) | VAF 11/51 reads (22%) | catalogued as COSV60995193; called by mutect2, pindel, varscan2
- SLC35C2 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs187394710; called by muse, mutect2
- SLC39A12 | c.1585G>T p.A529S (on ENST00000377369 / NM_001145195.2; = p.A492S on NM_152725.3) | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as COSV66195308; called by muse, mutect2, varscan2
- SLC39A13 | c.695A>G p.H232R | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100712639; called by muse, mutect2, varscan2
- SLC3A2 | c.1556T>C p.L519P | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100101245; called by muse, mutect2, varscan2
- SLC45A4 | c.1291G>A p.G431S (on ENST00000517878 / NM_001286646.2; = p.G380S on NM_001080431.2) | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs745745921, COSV50133362; called by muse, mutect2, varscan2
- SLC4A2 | c.2233A>G p.M745V | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs1239605906, COSV52539195; called by muse, mutect2, varscan2
- SLC5A10 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs778828313, COSV58760820; called by mutect2, varscan2
- SLC5A8 | c.388T>C p.C130R | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as rs754809263, COSV73310378; called by muse, mutect2
- SLC5A9 | c.559T>C p.Y187H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52582114; called by muse, mutect2, varscan2
- SLC6A12 | c.1702-1G>A p.X568_splice | Splice Site (SNP) | VAF 20/56 reads (36%) | catalogued as COSV62883952; called by muse, mutect2, varscan2
- SLC6A8 | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 36/53 reads (68%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.751); catalogued as rs782802482, COSV53471517; called by muse, mutect2, varscan2
- SLC8A2 | c.658del p.S220Pfs*12 | Frame Shift Del (DEL) | VAF 12/33 reads (36%) | catalogued as rs748349403; called by mutect2, pindel, varscan2
- SLC9A3R2 | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as rs891488832, COSV101424294; called by muse, mutect2, varscan2
- SLC9C1 | c.29del p.F10Sfs*11 | Frame Shift Del (DEL) | VAF 52/131 reads (40%) | catalogued as rs749004401; called by mutect2, varscan2
- SLX4 | c.3667C>T p.P1223S | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1469061695, COSV53561083; called by muse, varscan2
- SMARCD2 | c.1417C>T p.R473C | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs757140754, COSV56737942; called by muse, mutect2, varscan2
- SMG5 | c.2066T>C p.L689S | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs368680222; called by muse, mutect2, varscan2
- SMG5 | c.87G>T p.E29D | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.057); catalogued as COSV55293343; called by muse, mutect2, varscan2
- SMG6 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as rs985150326, COSV53963368; called by muse, mutect2, varscan2
- SNRNP200 | c.2216G>A p.R739Q | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV60487348; called by muse, mutect2, varscan2
- SNRNP35 | c.17C>A p.P6H | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV63471815; called by muse, mutect2, varscan2
- SNX29 | c.2183C>T p.A728V | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs1324125271, COSV100027570, COSV60051474; called by muse, mutect2, varscan2
- SOX21 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV65375099; called by muse, mutect2, varscan2
- SOX5 | c.221C>T p.T74M | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.112); catalogued as rs776219045, COSV58619269; called by muse, mutect2, varscan2
- SOX6 | c.2165G>T p.R722M (on ENST00000528429 / NM_001145819.2; = p.R695M on NM_017508.3) | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100321370; called by muse, mutect2, varscan2
- SOX7 | c.769del p.L257Wfs*14 | Frame Shift Del (DEL) | VAF 17/45 reads (38%) | catalogued as rs1478777952; called by mutect2, pindel, varscan2
- SPEG | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as rs759418830, COSV56663544; called by muse, mutect2, varscan2
- SPEG | c.2607dup p.T870Hfs*52 | Frame Shift Ins (INS) | VAF 8/27 reads (30%) | catalogued as rs1403844185; called by mutect2, pindel
- SPNS3 | c.235A>G p.S79G | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.02); catalogued as COSV100336874; called by muse, mutect2
- SPNS3 | c.1177C>T p.L393= | Splice Region (SNP) | VAF 15/40 reads (38%) | catalogued as COSV61069140; called by muse, mutect2, varscan2
- SPTBN2 | c.3679C>T p.R1227W | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs766811381, COSV59447657; called by muse, mutect2, varscan2
- SPTBN2 | c.3380T>C p.L1127P | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV100018366; called by muse, mutect2
- SRCAP | c.5633del p.P1878Hfs*89 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | catalogued as rs748467821; called by mutect2, varscan2
- SRCAP | c.8861T>G p.I2954S | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV52667801; called by muse, mutect2, varscan2
- SRFBP1 | c.932A>C p.E311A | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV59581685; called by muse, mutect2, varscan2
- SRGAP1 | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866227246, COSV61894669; called by muse, mutect2, varscan2
- SRL | c.581T>G p.I194S | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV68422873; called by muse, mutect2, varscan2
- STAB1 | c.4015del p.V1339Cfs*252 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | catalogued as rs761841917, COSV100402435; called by mutect2, varscan2
- STAB2 | c.3542C>T p.A1181V | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV66334733; called by muse, mutect2, varscan2
- STAMBPL1 | c.1214del p.K405Rfs*21 | Frame Shift Del (DEL) | VAF 18/39 reads (46%) | catalogued as rs752994755; called by mutect2, varscan2
- STX11 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV62448525; called by muse, mutect2, varscan2
- STX19 | c.829del p.R277Efs*? | Frame Shift Del (DEL) | VAF 16/62 reads (26%) | catalogued as rs745879072; called by mutect2, pindel, varscan2
- SUPT7L | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs752015900, COSV100389156, COSV58133704; called by muse, mutect2, varscan2
- SV2C | c.793T>C p.Y265H | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV59214631; called by muse, mutect2, varscan2
- SVEP1 | c.695A>G p.N232S | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.63); catalogued as rs1226148789, COSV57029579; called by muse, mutect2, varscan2
- SVIL | c.5586del p.M1863Wfs*44 (on ENST00000355867 / NM_021738.3; = p.M1437Wfs*44 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 21/54 reads (39%) | catalogued as rs770033147; called by mutect2, varscan2
- SVIL | c.837A>C p.K279N | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.638); catalogued as COSV63440081; called by muse, mutect2, varscan2
- SYCP2 | c.2362del p.M788* | Frame Shift Del (DEL) | VAF 13/95 reads (14%) | catalogued as rs570102997; called by mutect2, varscan2
- SYCP2 | c.1936A>T p.I646L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.011); catalogued as COSV62765970; called by muse, mutect2, varscan2
- TACC2 | c.6891G>A p.M2297I (on ENST00000334433; = p.M375I on NM_006997.4) | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1448852295, COSV99586695; called by muse, mutect2, varscan2
- TAF5L | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs374711429, COSV51077420; called by muse, mutect2, varscan2
- TANC1 | c.2908A>C p.T970P | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV55083448; called by muse, mutect2, varscan2
- TAOK2 | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV54233266; called by muse, mutect2, varscan2
- TAP1 | c.473C>A p.P158Q | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV62753805; called by muse, mutect2, varscan2
- TARDBP | c.1177T>C p.S393P | Missense Mutation (SNP) | VAF 72/172 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.245); catalogued as COSV99534050; called by muse, mutect2, varscan2
- TAS2R13 | c.800A>G p.E267G | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.139); catalogued as COSV66831483; called by muse, mutect2, varscan2
- TAS2R14 | c.878C>T p.S293L | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.225); catalogued as COSV67852580; called by muse, mutect2, varscan2
- TAS2R60 | c.530C>A p.P177H | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.738); catalogued as COSV60330094; called by muse, mutect2, varscan2
- TBC1D14 | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV63391571; called by muse, mutect2, varscan2
- TBC1D16 | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as rs758918595, COSV100187766; called by muse, mutect2
- TBCD | c.7C>A p.L3M | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.462); catalogued as COSV56181398; called by muse, mutect2, varscan2
- TBRG4 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.098); catalogued as rs747633730, COSV99345279; called by muse, mutect2, varscan2
- TBXA2R | c.314G>A p.C105Y | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64343170; called by muse, mutect2, varscan2
- TCF3 | c.878_880del p.F293del | In Frame Del (DEL) | VAF 6/19 reads (32%) | catalogued as rs748560717; called by mutect2, varscan2
- TCF7L1 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.212); catalogued as rs753284958, COSV56396359; called by muse, mutect2, varscan2
- TDG | c.252dup p.S85Ifs*19 | Frame Shift Ins (INS) | VAF 88/230 reads (38%) | catalogued as rs762845105; called by mutect2, varscan2
- TEC | c.550G>A p.V184I | Missense Mutation (SNP) | VAF 80/235 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as rs539573453, COSV67403516; called by muse, mutect2, varscan2
- TECTA | c.1568A>G p.Y523C | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs750520238, COSV50688564; called by muse, varscan2
- TEFM | c.427del p.R143Efs*9 | Frame Shift Del (DEL) | VAF 37/99 reads (37%) | catalogued as rs1567706506; called by mutect2, pindel, varscan2
- TH | c.677C>T p.S226L (on ENST00000381178 / NM_199292.3; = p.S195L on NM_000360.4) | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as rs372409517; ClinVar: uncertain significance; called by muse, mutect2, varscan2
557 further variants in this file (269 protein-altering or splice-affecting, 263 silent, 25 other) are not listed here.
